Surgical pathology report (de-identified scan), TCGA case TCGA-W7-A93O, project TCGA-CHOL (Cholangiocarcinoma), tissue source site Garvan Institute of Medical Research, specimen TCGA-W7-A93O-01A (Primary Tumor).

[page 1 of 4]
ICD-0-3
Cholangiocarcinoma 8160/3
Site: Common bile duct C25.
GAS 2/16/14

Received

SPECIMEN TYPE: Whipples

CLINICAL NOTES:
Whipple's specimen ?cholangiocarcinoma.
R/O gallstones. E/O neural tissue on common hepatic artery.

Frozen section report:
Adenocarcinoma is clear of the bile duct margin. Message to .

MACROSCOPIC:
A) "Whipple's specimen". The specimen was received fresh for frozen section opinion and consists of a whipple's specimen.

SYNOPTIC REPORT FOR WHIPPLE'S RESECTION

Specimen labelled: Whipple's specimen.

Specimen Type:
Pancreaticoduodenectomy (Whipple's resection), partial pancreatectomy

Specimen dimensions:
Length of duodenum: 200mm.
Length of lesser curve of stomach: 70mm.
Length of greater curve of stomach: 90mm.
Size of gallbladder: 100 x 50 x 45mm.
Wall thickness of gallbladder: 8mm.
Calculi in gallbladder: There is a single stone within the container 20mm with a yellow and brown smooth external appearance. There are further fragments of stones with similar appearances within the body.
Size of and weight of spleen: Not included.
Length of bile duct: 20mm.
Maximum diameter of bile duct: 5mm.
Size of pancreas: 80 x 50 x 20mm.
Location of stent: Not included.

Tumour location:
Cystic duct of gallbladder.

Tumour:
Configuration: Firm, white and infiltrative.
Description: Firm.

[page 2 of 4]
Received

SPECIMEN TYPE: Whipples

Tumour Size:

Greatest dimension: 35 mm

*Additional dimensions: 25 x 20 mm

Distance of tumour to margins:

Pancreatic neck: 20mm.

Periuncinate (retroperitoneal) soft tissue: 25mm.

Posterior: 25mm.

Portal vein bed: 25mm.

Anterior pancreatic capsule: 25mm.

Common bile duct: 5mm.

Proximal intestinal/gastric: 100mm.

Distal intestinal margin: 200mm.

Length of segment of superior mesenteric vein present in resection specimen:

Absent

Additional gross pathologic findings: None.

Blocks 1&2: neck margin

Block 3: bile duct margin

Block 4: adjacent to bile duct

Blocks 5&6: tumour

Block 7: tumour

Block 8: proximal gastric margin

Block 9: distal duodenal margin

Blocks 10-12: tumour

Block 13: tumour

Blocks 14&15: further common bile duct

Blocks 16-18: gallbladder with attached liver

Blocks 19-21: representative gallbladder wall

Block 22: neck margin

Blocks 23-24: portal vein bed

Block 25: periuncinate margin

Block 26: posterior pancreatic capsule

Blocks 27&28: anterior pancreatic capsule

Block 29: representative omentum

Block 30: possible perigastric nodes

Blocks 31&32: peripancreatic nodes

[page 3 of 4]
Received

SPECIMEN TYPE: Whipples

Block 33: lymphovascular tissue

B) "Periarteriole neural tissue right hepatic". The specimen consists of a 5mm piece of grey glistening tissue. Embedded whole in one block.

MICROSCOPIC:

SYNOPTIC REPORT FOR WHIPPLE'S RESECTION:

Tumour location: Common bile duct
Histologic type (WHO classification): Adenocarcinoma the extrahepatic bile duct (cholangiocarcinoma)
Histologic grade (TNM grading system): G3 (poorly differentiated)
Tumour size: 35mm
Extension out of pancreas: Absent
Extension beyond the wall of the common bile duct: Present
Small vessel (capillary/lymphatic) invasion: Present
Large vessel (vein/artery) invasion: Absent
Perineural invasion: Present
Perineural invasion of retroperitoneal (periuncinate) neural plexus: Absent

Distance of invasive tumour from resection margins:

Pancreatic neck: 20mm
Periuncinate (retroperitoneal) soft tissue: 25mm
Posterior: 25mm
Portal vein bed: 25mm
Common bile duct: 5mm

Lymph nodes from main resection specimen: Metastatic carcinoma is present in 4 of 12 lymph nodes from the main resection specimen

Separately received lymph nodes:

Specimen B ('Periarteriole neural tissue right hepatic') the specimen comprises fibrocollagenous and neural tissue only. No lymph nodes are present. There is no evidence of malignancy.

Highest grade of Pan-In present: PanIN1B
Grade of Pan-In at pancreatic neck resection margin: Absent

Pathologic Staging (pTNM, AJCC 7th edition 2009)

Staged as: Adenocarcinoma of the distal bile duct

[page 4 of 4]
Received

SPECIMEN TYPE: Whipples

pT: pT3

pN: pN1

Overall stage: p2B

Additional pathologic comments and findings in other resected organs:

The gallbladder shows acute cholecystitis.

HER2 Immunohistochemistry and In-situ Hybridization studies (all tumours):

Pending

Two representative blocks containing tumour: A5, A10

SUMMARY:

Tumour type: Adenocarcinoma of the common bile duct (cholangiocarcinoma)

Tumour grade: G3 (poorly differentiated)

Tumour location: common bile duct

Tumour size: 35mm

Lymph nodes: Metastatic carcinoma is present in 4 of 12 lymph nodes.

Stage: p2B(T3N1)

Margins: Local excision is complete

ADDITIONAL REPORT:

Her2 studies are as follows:

Her2 IHC: Non-specific staining only (Her2 score 1)

HER2 ISH: Not amplified.

Note: Her2 IHC and ISH is currently not a accredited test for pancreatic carcinoma and this result should be considered experimental only.

Source: NCI Genomic Data Commons file c7f736e1-c462-4df2-a535-765ed284e288 (TCGA-W7-A93O.0DCE887A-1EE8-4A56-A1E4-B2813F92945C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).